Somatic mutation profile of tumor specimen TCGA-IN-8462-01A (aliquot TCGA-IN-8462-01A-11D-2340-08) from TCGA case TCGA-IN-8462, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 80.1 years (29,242 days).
Specimen TCGA-IN-8462-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f4a2f76-f049-405c-8a7c-8203900decf4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IN-8462-10A (Blood Derived Normal), aliquot TCGA-IN-8462-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/101cc7b9-e448-46e7-9043-2c75b91b98ef

The open-access MAF lists 129 somatic variants for this specimen: 100 protein-altering or splice-affecting, 24 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 24, Nonsense Mutation 4, Frame Shift Ins 4, Intron 3, Frame Shift Del 3, Splice Site 2, Translation Start Site 1, In Frame Del 1, 5'Flank 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RIMS1 | c.211A>G p.R71G | Missense Mutation (SNP) | VAF 24/104 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV53441304, COSV53444045, COSV53451865; called by muse, mutect2, varscan2
- SLC19A3 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121917882, CM051990, COSV51452421; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455dup p.P153Afs*28 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | catalogued as rs730882019, COSV53468298, COSV99394349; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA13 | c.12021C>A p.D4007E | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101446959; called by muse, mutect2, varscan2
- ADCY10 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 22/90 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV63240189; called by muse, mutect2, varscan2
- AKAP14 | c.261G>A p.S87= | Splice Region (SNP) | VAF 16/24 reads (67%) | catalogued as COSV57629930; called by muse, mutect2, varscan2
- APBB1 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV54974908; called by muse, mutect2, varscan2
- ARID3A | c.1644C>G p.N548K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.027); catalogued as COSV55044239; called by muse, mutect2
- BAD | c.488G>A p.S163N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as rs199759687, COSV54187807; called by muse, mutect2, varscan2
- BAZ1A | c.4438C>T p.R1480C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV62409067, COSV62409929; called by muse, mutect2, varscan2
- C12orf66 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as rs1377065647, COSV61322974; called by muse, mutect2, varscan2
- C16orf46 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100215296, COSV55150884; called by muse, mutect2
- CADM1 | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV59008613; called by muse, mutect2, varscan2
- CCDC50 | c.1412C>T p.S471L (on ENST00000392455 / NM_178335.3; = p.S295L on NM_174908.4) | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as COSV66667746; called by muse, mutect2, varscan2
- CFHR3 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.713); catalogued as rs574536456, COSV66401862; called by muse, mutect2, varscan2
- CHL1 | c.1565A>G p.K522R (on ENST00000397491 / NM_001253387.1; = p.K538R on NM_006614.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV56591350; called by muse, mutect2, varscan2
- COL5A1 | c.4175G>T p.R1392M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65665394, COSV65667512; called by muse, mutect2, varscan2
- CORO2B | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs926965860, COSV55952260; called by muse, mutect2, varscan2
- CSMD3 | c.7228G>A p.D2410N (on ENST00000297405 / NM_001363185.1; = p.D2306N on NM_052900.3) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.999); catalogued as COSV52159870; called by muse, mutect2, varscan2
- CYLC2 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.257); catalogued as COSV66337245; called by muse, mutect2, varscan2
- DDHD2 | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.598); catalogued as COSV68157732; called by muse, mutect2, varscan2
- DENND4A | c.2893G>A p.V965I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs748829507, COSV71265181; called by muse, mutect2, varscan2
- DLGAP3 | c.667C>A p.H223N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.135); catalogued as COSV52393435; called by muse, mutect2, varscan2
- DMGDH | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54862758, COSV54866558; called by muse, mutect2, varscan2
- DOCK1 | c.3670T>C p.C1224R | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV54737312; called by muse, mutect2, varscan2
- ENPP5 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as rs201147736, COSV57908513; called by muse, mutect2, varscan2
- ERBB4 | c.3659A>C p.E1220A | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV61473135, COSV61481384; called by muse, mutect2
- FLG | c.3803C>A p.S1268Y | Missense Mutation (SNP) | VAF 66/265 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV64240655; called by muse, mutect2, varscan2
- FMN2 | c.3380C>T p.A1127V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs565779798, COSV60427514, COSV60462631; called by muse, varscan2
- GNPNAT1 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53591289; called by muse, mutect2, varscan2
- GP2 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.155); catalogued as COSV56893136; called by muse, mutect2, varscan2
- GRIK4 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs773499648, COSV70801832; called by muse, mutect2, varscan2
- GRIK4 | c.791A>T p.N264I | Missense Mutation (SNP) | VAF 154/291 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV70801835; called by muse, mutect2, varscan2
- GRM7 | c.1114T>G p.F372V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63140426, COSV63151123; called by mutect2, varscan2
- H4C8 | c.224_225del p.E75Afs*54 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | catalogued as rs763786502; called by pindel, varscan2
- HEPH | c.3205T>G p.L1069V (on ENST00000343002; = p.L802V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV57962236; called by muse, mutect2, varscan2
- HMCN1 | c.14312G>A p.R4771Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as rs141397809, COSV99633123; called by muse, mutect2, varscan2
- IGHV3-23 | c.160A>G p.S54G | Missense Mutation (SNP) | VAF 51/283 reads (18%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs782264567; called by muse, mutect2, varscan2
- IL17RC | c.1428C>A p.D476E (on ENST00000295981 / NM_153461.4; = p.D390E on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.152); catalogued as COSV55972968; called by muse, mutect2, varscan2
- IQGAP3 | c.4792C>A p.Q1598K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV63250871; called by muse, mutect2, varscan2
- ISX | c.71C>A p.P24Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV100434096, COSV58086960; called by muse, mutect2, varscan2
- KIAA1586 | c.1507T>C p.Y503H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.827); catalogued as rs747731774, COSV66056470; called by muse, mutect2, varscan2
- KLHL21 | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV66553348; called by muse, mutect2, varscan2
- KLHL4 | c.992T>G p.L331R | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64141545; called by muse, mutect2, varscan2
- KRT36 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as rs757664985, COSV60203161; called by muse, mutect2, varscan2
- KRT6C | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs760872674, COSV99359990; called by muse, mutect2, varscan2
- LRFN5 | c.341T>G p.I114S | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV53253088; called by muse, mutect2, varscan2
- LRRC8B | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764304785, COSV58374444; called by muse, mutect2, varscan2
- MED23 | c.146del p.G49Vfs*35 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | catalogued as rs1196639355; called by mutect2, pindel, varscan2
- MLKL | c.863T>G p.L288R | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.035); catalogued as COSV58204873; called by muse, mutect2, varscan2
- MYO16 | c.4022G>T p.S1341I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV62749142; called by muse, mutect2, varscan2
- NCR1 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as COSV52556356; called by muse, mutect2, varscan2
- NDRG4 | c.370G>T p.A124S (on ENST00000570248 / NM_001378344.1; = p.A156S on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV50747371; called by muse, mutect2, varscan2
- NETO1 | c.1337A>C p.N446T | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.132); catalogued as COSV55005281; called by muse, mutect2, varscan2
- NEUROD1 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV54549001; called by muse, mutect2, varscan2
- ORC1 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV65363723; called by muse, mutect2, varscan2
- PCDHB9 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.829); catalogued as rs782272485, COSV53378001; called by muse, mutect2, varscan2
- PIK3C3 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as rs778354842, COSV100011753, COSV56278436; called by muse, mutect2, varscan2
- PIWIL3 | c.257A>G p.H86R | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV59994937; called by muse, mutect2, varscan2
- PKD1 | c.11092G>T p.A3698S (on ENST00000262304 / NM_001009944.3; = p.A3697S on NM_000296.4) | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.672); catalogued as COSV51914544, COSV51917542; called by muse, varscan2
- PLCL1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70826880; called by muse, mutect2
- PM20D1 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV65648828; called by muse, mutect2, varscan2
- PNMA5 | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62625524; called by muse, mutect2, varscan2
- POLQ | c.1920G>T p.K640N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV51750179; called by muse, mutect2, varscan2
- PRKD1 | c.1357C>T p.L453F | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.582); catalogued as rs780895625, COSV59566289; called by muse, mutect2, varscan2
- RAP2A | c.419G>T p.C140F | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV55354896; called by muse, mutect2, varscan2
- RFTN1 | c.233C>A p.S78* | Nonsense Mutation (SNP) | VAF 24/80 reads (30%) | catalogued as COSV61918404, COSV61921475; called by muse, mutect2, varscan2
- RGS11 | c.443G>C p.R148P (on ENST00000397770 / NM_183337.3; = p.R127P on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.214); catalogued as COSV99395796; called by muse, mutect2, varscan2
- ROR1 | c.1720G>A p.G574S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.934); catalogued as COSV64286527; called by muse, mutect2, varscan2
- SEC14L1 | c.64-2A>T p.X22_splice | Splice Site (SNP) | VAF 19/52 reads (37%) | catalogued as COSV66721455; called by muse, mutect2, varscan2
- SIGLEC14 | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55779153, COSV55783856; called by muse, mutect2, varscan2
- SLC4A2 | c.3091G>A p.G1031S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376108278; called by muse, mutect2, varscan2
- SNX14 | c.26G>C p.G9A | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as COSV59011367; called by muse, mutect2, varscan2
- SPEG | c.2776C>T p.R926W | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs763189226, COSV56667348; called by muse, mutect2, varscan2
- SYNDIG1L | c.398A>G p.D133G | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1284388199, COSV59047366; called by muse, mutect2, varscan2
- TCERG1 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs758260296, COSV57033505; called by muse, mutect2, varscan2
- THSD7B | c.2720G>A p.C907Y | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55678263; called by muse, mutect2, varscan2
- TICRR | c.3228G>T p.M1076I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV51540685; called by muse, mutect2, varscan2
- TIE1 | c.1759G>A p.G587R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.538); catalogued as rs770948609, COSV65249964; called by muse, mutect2, varscan2
- TMEM213 | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV59474823; called by muse, mutect2, varscan2
- TNFRSF19 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99947379; called by muse, varscan2
- TNS3 | c.2945C>A p.S982Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as rs1462773898, COSV60790018; called by muse, mutect2, varscan2
- TRAP1 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs775599442, COSV55915903; called by muse, mutect2, varscan2
- TRERF1 | c.1997C>T p.P666L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs928875702, COSV61670535; called by mutect2, varscan2
- TRPM4 | c.45C>A p.F15L | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as rs1009277467, COSV53256016; called by muse, mutect2, varscan2
- TSHZ3 | c.1612C>A p.Q538K | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV53669625; called by muse, mutect2
- TSPYL5 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as rs1463529759, COSV59071451; called by muse, mutect2, varscan2
- VARS2 | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs370284242; called by muse, mutect2
- VWA7 | c.2402T>C p.V801A | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV65173045; called by muse, mutect2, varscan2
- XRN1 | c.4676C>T p.S1559L | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.035); catalogued as rs552700387, COSV53810653; called by muse, mutect2, varscan2
- ZNF491 | c.1208G>T p.R403I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs566438546, COSV60056711, COSV60058183; called by muse, mutect2, varscan2
- ZNF75D | c.503C>A p.P168Q | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1556421530, COSV66132652; called by muse, mutect2, varscan2
- ABCC9 | c.1509dup p.L504Tfs*25 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- FRG2C | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- IRF2BP2 | c.1209dup p.T404Hfs*13 | Frame Shift Ins (INS) | VAF 12/69 reads (17%) | called by mutect2, pindel, varscan2
- PIK3C2G | c.1309dup p.I437Nfs*19 | Frame Shift Ins (INS) | VAF 20/77 reads (26%) | called by mutect2, varscan2
- SARNP | c.304-1G>A p.X102_splice | Splice Site (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- TRIP12 | c.3009A>T p.K1003N | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); called by muse, mutect2
- ZC3H4 | c.634_648del p.M212_D216del | In Frame Del (DEL) | VAF 12/74 reads (16%) | called by mutect2, varscan2
- ZDHHC22 | c.667del p.V223Wfs*3 | Frame Shift Del (DEL) | VAF 9/20 reads (45%) | called by mutect2, pindel, varscan2
- ADAMTS10 | c.519A>G p.E173= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV54353958; called by muse, mutect2, varscan2
- ADAMTS8 | c.603G>A p.P201= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV57292914; called by muse, mutect2, varscan2
- AKR7A3 | c.468C>G p.L156= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV64389234; called by muse, mutect2, varscan2
- AR | c.894C>T p.S298= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as CM005383, COSV65955570, COSV65957432; called by muse, mutect2, varscan2
- CCNB3 | c.3609A>G p.L1203= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as COSV52072565; called by muse, mutect2, varscan2
- CD300A | c.414G>A p.A138= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs1008144753, COSV60409917, COSV60410568; called by muse, mutect2, varscan2
- CERCAM | c.612C>T p.R204= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as COSV65710804; called by muse, mutect2, varscan2
- FCAR | c.201G>A p.T67= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs779070630, COSV62029299; called by muse, mutect2, varscan2
- GRM2 | c.1731C>T p.L577= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs778457396, COSV56584449; called by muse, mutect2, varscan2
- KCNK13 | c.990C>T p.D330= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs139112374; called by muse, mutect2, varscan2
- LRRC4B | c.625C>T p.L209= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV65349890; called by muse, mutect2, varscan2
- MAP3K12 | c.873C>A p.V291= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as COSV57232440; called by muse, mutect2, varscan2
- MUC5B | c.5229G>C p.T1743= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV71591587; called by muse, mutect2
- OR9G4 | c.900C>A p.A300= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV57248306; called by muse, mutect2, varscan2
- P2RY1 | c.609C>T p.Y203= | Silent (SNP) | VAF 54/101 reads (53%) | catalogued as rs1045138243, COSV59308851; called by muse, mutect2, varscan2
- PDZRN4 | c.1056T>A p.P352= (on ENST00000402685 / NM_001164595.2; = p.P94= on NM_013377.4) | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV54199005; called by muse, mutect2, varscan2
- RBM12B | c.2304A>G p.P768= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as rs199643296; called by muse, varscan2
- SEC14L5 | c.2034C>T p.A678= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs537226718, COSV52038025; called by muse, mutect2, varscan2
- SLC22A12 | c.489C>T p.C163= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs780944605, COSV60571414; called by muse, mutect2
- SLTM | c.1569T>C p.G523= | Silent (SNP) | VAF 48/73 reads (66%) | catalogued as COSV51053920; called by muse, mutect2, varscan2
- TXNDC9 | c.282C>T p.C94= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV51811254; called by muse, mutect2, varscan2
- VRK3 | c.741C>T p.F247= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs748321297, COSV57465509; called by muse, mutect2, varscan2
- WDR91 | c.864G>A p.S288= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV60369470; called by muse, mutect2, varscan2
- WSCD2 | c.1521G>T p.L507= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs767874569, COSV54581618; called by muse, mutect2, varscan2
- ADGRL3 | c.3944-1939C>A | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- IGLL3P | n.383G>T | RNA (SNP) | VAF 10/52 reads (19%) | catalogued as rs767184795; called by muse, mutect2
- NRG1 | c.502+31341C>T | Intron (SNP) | VAF 28/96 reads (29%) | catalogued as rs140245897; called by muse, mutect2, varscan2
- RBFOX1 | c.28-185080T>A | Intron (SNP) | VAF 29/121 reads (24%) | catalogued as rs1366973960, COSV100301361; called by muse, mutect2, varscan2
- ZNFX1 | chr20:49278975 C>G | 5'Flank (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
